Gene-level copy-number profile of tumor specimen MP2PRT-PAWPUL-TTM2-A from MP2PRT case MP2PRT-PAWPUL, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 12.0 years (4,390 days).
Specimen MP2PRT-PAWPUL-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2419bfab-cc33-4372-90de-69ca65f03d6b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAWPUL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/48773b1f-ad2d-44e4-a512-cca4894e6698

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,039; copy number 2: 49,425; copy number 3: 7,899; copy number 4: 40.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,039. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
